Gene-level copy-number profile of tumor specimen ALCH-B3ZP-TTP1-A from ALCHEMIST case ALCH-B3ZP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,135 days).
Specimen ALCH-B3ZP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96b58c83-6014-4e09-9d3c-4ddd9752f4bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/3188ab0c-d40a-42c4-aed0-c7c7d3141449

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 10,322; copy number 2: 44,041; copy number 3: 3,690; copy number 4: 733; copy number 5: 63; copy number 7: 5; copy number 8: 2; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,571,481–4,594,016, 1 gene: LINC01646.
- chr1:12,892,896–12,898,270, 1 gene (within-gene range 0–1): PRAMEF10.
- chr1:13,049,476–13,155,961, 8 genes (within-gene range 0–3): PRAMEF27, HNRNPCL3, PRAMEF25, PRAMEF35P, HNRNPCL2, PRAMEF36P, AC245056.1, PRAMEF26.
- chr1:13,222,705–13,248,652, 2 genes: PRAMEF18, PRAMEF31P.
- chr1:58,060,139–58,084,559, 2 genes (within-gene range 0–1): AL445193.2, AL445193.1.
- chr2:131,461,821–131,463,615, 1 gene: AC073869.1.
- chr3:53,812,335–53,846,419, 1 gene (within-gene range 0–2): CHDH.
- chr3:75,415,070–75,422,143, 1 gene (within-gene range 0–1): ALG1L6P.
- chr4:3,633,029–3,633,975, 1 gene: AL121796.1.
- chr5:2,712,591–2,715,237, 1 gene: LSINCT5.
- chr6:63,229,087–63,230,110, 1 gene: AL450346.2.
- chr6:150,164,584–150,164,686, 1 gene (within-gene range 0–1): AL355497.3.
- chr6:168,225,279–168,240,715, 2 genes: AL606970.4, AL606970.2.
- chr7:63,495,799–63,502,536, 1 gene: SEPTIN7P5.
- chr7:63,768,257–63,771,047, 1 gene: CICP24.
- chr13:18,807,279–18,808,018, 1 gene: SNX18P26.
- chr13:19,345,049–19,346,749, 1 gene: LINC00421.
- chr13:27,960,918–27,969,315, 1 gene: CDX2.
- chr13:29,239,379–29,250,554, 1 gene (within-gene range 0–1): MTUS2-AS2.
- chr19:43,064,209–43,083,045, 1 gene (within-gene range 0–1): PSG2.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.
- chr22:48,448,890–48,451,217, 1 gene: Z82249.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 72 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,172,455–13,179,464, 1 gene, copy number 5: PRAMEF9.
- chr1:151,156,649–151,267,479, 7 genes, copy number 5: TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4.
- chr1:153,658,703–153,718,347, 6 genes, copy number 5: SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1.
- chr1:156,463,727–156,625,725, 9 genes, copy number 5: MEF2D, Y_RNA, AL365181.1, IQGAP3, TTC24, NAXE, GPATCH4, AL365181.4, HAPLN2.
- chr1:221,701,424–221,742,089, 1 gene, copy number 5: DUSP10.
- chr1:221,880,981–221,984,964, 2 genes, copy number 5: LINC02257, LINC02474.
- chr1:222,712,553–222,773,149, 3 genes, copy number 5 (within-gene range 4–5): BROX, FAM177B, AL392172.1.
- chr3:152,243,828–152,465,780, 4 genes, copy number 5 (within-gene range 3–5): MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA.
- chr6:3,055,849–3,057,357, 1 gene, copy number 5: AL031963.2.
- chr6:7,107,597–7,251,980, 4 genes, copy number 5: RREB1, AL355336.1, Y_RNA, AL589644.1.
- chr6:11,154,929–11,807,046, 14 genes, copy number 5: AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3.
- chr6:26,440,472–26,476,621, 2 genes, copy number 5: BTN3A3, BTN2A1.
- chr6:30,798,654–30,830,659, 1 gene, copy number 5: LINC00243.
- chr6:43,037,617–43,053,945, 1 gene, copy number 5 (within-gene range 3–5): CUL7.
- chr6:43,995,723–44,089,288, 3 genes, copy number 5 (within-gene range 3–5): AL109615.3, C6orf223, AL109615.2.
- chr7:63,348,861–63,359,306, 4 genes, copy number 7 (within-gene range 7–8): AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr9:137,039,463–137,046,179, 1 gene, copy number 9 (within-gene range 1–9): NPDC1.
- chr11:65,487,241–65,488,896, 2 genes, copy number 8: LINC02736, AP000769.6.
- chr14:18,333,726–18,341,859, 1 gene, copy number 10: CR383658.1.
- chr14:18,418,775–18,419,273, 1 gene, copy number 7: BNIP3P6.
- chr20:50,510,321–50,585,241, 4 genes, copy number 5: PTPN1, RN7SL672P, Y_RNA, AL133230.1.

Autosomal genes at a single copy (total copy number 1): 7,466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
